Somatic mutation profile of tumor specimen MMRF_2137_1_BM_CD138pos (aliquot MMRF_2137_1_BM_CD138pos_T1_KHS5U_L08635) from MMRF case MMRF_2137, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.6 years (25,066 days).
Specimen MMRF_2137_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bd3e99f-f349-4b47-be27-147e1c4e6160.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2137_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2137_1_PB_Whole_C2_KHS5U_L08636; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14893317-8002-4e8c-8b6c-4be8fcd3003f

The open-access MAF lists 86 somatic variants for this specimen: 34 protein-altering or splice-affecting, 13 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 23, Silent 13, Intron 10, RNA 3, Splice Site 2, 5'UTR 2, Nonsense Mutation 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.14640+1G>T p.X4880_splice | Splice Site (SNP) | VAF 8/91 reads (9%) | catalogued as COSV68951348; called by muse, mutect2
- CDH10 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV52594580; called by muse, mutect2, varscan2
- COPZ1 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs749537933, COSV50432667; called by muse, mutect2, varscan2
- GNPTAB | c.2808A>T p.R936S | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1331945263, CS134993; called by muse, mutect2, varscan2
- GTSE1 | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as rs767037549; called by muse, mutect2, varscan2
- IGFN1 | c.3407G>A p.R1136Q (on ENST00000295591 / NM_001367841.1; = p.R3593Q on NM_001164586.2) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs772963488, COSV55185350; called by muse, mutect2
- MAPK8IP3 | c.3214C>T p.P1072S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs749973937, COSV51601194; called by mutect2, varscan2
- MED14 | c.4037C>T p.A1346V | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV61356152; called by muse, mutect2, varscan2
- MKRN3 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58809061; called by muse, mutect2, varscan2
- RASAL3 | c.689A>C p.E230A | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59138272; called by muse, mutect2, varscan2
- ROCK1 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs767793486; called by muse, mutect2, varscan2
- ROS1 | c.3118+1G>C p.X1040_splice | Splice Site (SNP) | VAF 22/75 reads (29%) | catalogued as rs747426279; called by muse, mutect2, varscan2
- SOX1 | c.234C>A p.N78K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100446762; called by muse, mutect2, varscan2
- TBCD | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100833274; called by muse, mutect2
- TRPC5 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1459235969, COSV53284163; called by muse, mutect2
- WASF1 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs746382726; called by mutect2, varscan2
- ZZEF1 | c.6658G>A p.D2220N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV101067792; called by muse, mutect2, varscan2
- ABCA13 | c.10002T>A p.A3334= | Splice Region (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- AC073610.2 | c.508T>C p.S170P | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated, low confidence (0.11); called by muse, mutect2, varscan2
- CYP8B1 | c.92G>A p.W31* | Nonsense Mutation (SNP) | VAF 7/133 reads (5%) | called by muse, mutect2
- DNAH17 | c.38A>G p.E13G | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2
- EXOSC10 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGCT | c.23A>G p.D8G | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- IFT172 | c.307A>G p.K103E | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGSF1 | c.1496G>T p.S499I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IL10RB | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- MS4A8 | c.575G>T p.C192F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- OR6F1 | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- PABPC5 | c.181T>G p.Y61D | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHF14 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PRPF31 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM15 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLC13A1 | c.775A>C p.T259P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRDV1 | c.325T>A p.Y109N | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGAP36 | c.444C>T p.G148= | Silent (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- ARHGEF26 | c.435C>A p.R145= | Silent (SNP) | VAF 60/101 reads (59%) | catalogued as rs780634190; called by muse, mutect2, varscan2
- ASXL2 | c.2490G>A p.E830= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV55470423; called by muse, mutect2, varscan2
- CLCA4 | c.1071T>C p.N357= | Silent (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- DIXDC1 | c.1884G>A p.K628= (on ENST00000440460 / NM_001037954.4; = p.K417= on NM_033425.4) | Silent (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- DNAH12 | c.4617T>C p.A1539= (on ENST00000351747; = p.A1562= on NM_001366028.2) | Silent (SNP) | VAF 3/51 reads (6%) | catalogued as COSV61066114; called by muse, mutect2
- DNAH5 | c.6630A>C p.P2210= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- FAM120B | c.1398C>T p.G466= | Silent (SNP) | VAF 24/239 reads (10%) | called by muse, mutect2
- GABRB3 | c.1320T>C p.P440= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs1209124720; called by muse, mutect2, varscan2
- GOLGB1 | c.3801A>G p.L1267= | Silent (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- KCNJ15 | c.474C>T p.I158= | Silent (SNP) | VAF 58/235 reads (25%) | catalogued as COSV60811475; called by muse, mutect2, varscan2
- LMOD3 | c.195C>T p.N65= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs369414278; called by muse, mutect2, varscan2
- MDFIC | c.135A>G p.Q45= | Silent (SNP) | VAF 72/323 reads (22%) | catalogued as rs757462663; called by muse, mutect2, varscan2
- ATRN | c.*3352C>G | 3'UTR (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- CALN1 | c.*1218G>T | 3'UTR (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- CGNL1 | c.*2371G>T | 3'UTR (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- FAR1 | c.1128-1390T>C | Intron (SNP) | VAF 13/64 reads (20%) | called by muse, varscan2
- FAR1 | c.1128-1382_1128-1360del | Intron (DEL) | VAF 12/69 reads (17%) | called by pindel, varscan2
- FHL1 | c.*475G>A | 3'UTR (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- FOXP1 | c.*1214C>T | 3'UTR (SNP) | VAF 16/50 reads (32%) | catalogued as rs1368788691; called by muse, mutect2, varscan2
- FSD1L | c.*2339C>G | 3'UTR (SNP) | VAF 18/66 reads (27%) | called by muse, varscan2
- HNF4G | chr8:75565235 A>C | 3'Flank (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- IGLL5 | c.-173A>G | 5'UTR (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- ITPK1 | c.*1378A>G | 3'UTR (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- JAG1 | c.1396-90G>A | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as rs1035687252, COSV54762055; called by muse, mutect2, varscan2
- KDR | c.*974G>A | 3'UTR (SNP) | VAF 5/54 reads (9%) | catalogued as rs1014095331; called by muse, mutect2
- KLHL4 | c.*396T>A | 3'UTR (SNP) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- LAMA1 | c.8094+39A>T | Intron (SNP) | VAF 11/130 reads (8%) | called by muse, mutect2
- LINC02118 | n.272T>A | RNA (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- MARCHF1 | c.*2687T>A | 3'UTR (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- OR4C50P | n.160A>G | RNA (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- PARP8 | c.*2555T>G | 3'UTR (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- PCDH15 | c.*1745C>T | 3'UTR (SNP) | VAF 7/29 reads (24%) | called by mutect2, varscan2
- PCLO | c.*140T>C | 3'UTR (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- PEG10 | c.-134C>A | 5'UTR (SNP) | VAF 46/221 reads (21%) | called by muse, varscan2
- PHF20L1 | c.848-107G>A | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as rs1456387094; called by muse, mutect2
- PISD | c.322-3913G>A | Intron (SNP) | VAF 53/100 reads (53%) | called by muse, mutect2, varscan2
- PTBP2 | c.*832T>G | 3'UTR (SNP) | VAF 23/33 reads (70%) | called by muse, mutect2, varscan2
- PTPRC | c.101-1784T>C | Intron (SNP) | VAF 7/66 reads (11%) | catalogued as rs1026369033; called by muse, mutect2, varscan2
- PTPRN2 | c.*1460A>G | 3'UTR (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- PTPRR | c.*940C>T | 3'UTR (SNP) | VAF 7/51 reads (14%) | catalogued as rs1200559068; called by muse, mutect2, varscan2
- SEC62 | c.36+2439G>A | Intron (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- SERTAD2 | c.*1157T>G | 3'UTR (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- SNX31 | c.*725G>T | 3'UTR (SNP) | VAF 5/25 reads (20%) | called by muse, varscan2
- SORD2P | n.1373G>T | RNA (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- STK38 | c.*574C>T | 3'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- TMEM91 | c.361-284C>T | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- TRAF3 | c.*5161G>A | 3'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- TTC13 | c.*144C>G | 3'UTR (SNP) | VAF 6/83 reads (7%) | catalogued as COSV100793025; called by muse, mutect2
- ZBTB46 | c.*1893T>G | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- ZNF623 | c.*2850A>T | 3'UTR (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- ZNF680 | c.254-2950G>A | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
